Gene-level copy-number profile of tumor specimen TCGA-05-4422-01A from TCGA case TCGA-05-4422, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-05-4422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2cc36772-2177-4308-991a-978feb47e0e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4422-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/adba2ce9-d8c7-41ba-8957-1d70811c522e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,236; copy number 2: 42,614; copy number 3: 3,317; copy number 4: 1,916; copy number 5: 169; copy number 6: 104; copy number 7: 82; copy number 9: 154; copy number 10: 44; copy number 11: 65; copy number 12: 24; copy number 15: 40; copy number 16: 26; copy number 19: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4422-01A-01D-1204-01): tumor purity 0.62, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 734 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,300,322, 8 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr8:62,191,088–64,369,176, 26 genes, copy number 6 (within-gene range 4–6): AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8.
- chr8:73,215,929–75,566,834, 52 genes, copy number 11: AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr8:76,904,591–78,153,913, 6 genes, copy number 10: AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1.
- chr8:84,665,759–85,379,014, 16 genes, copy number 6: RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1.
- chr8:86,707,547–86,765,023, 1 gene, copy number 5 (within-gene range 1–5): AC090572.3.
- chr8:94,201,913–104,256,094, 221 genes, copy number 5–12 (within-gene range 0–12) (broad region; genes not listed).
- chr8:112,148,742–112,148,825, 1 gene, copy number 11: RNU4-37P.
- chr8:117,794,490–118,111,826, 1 gene, copy number 7 (within-gene range 1–7): EXT1.
- chr8:123,288,355–141,308,305, 230 genes, copy number 5–19 (within-gene range 3–19) (broad region; genes not listed).
- chr8:141,507,333–143,023,832, 40 genes, copy number 5: AC138647.2, AC138647.1, AC025839.1, MIR1302-7, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2, LY6E-DT, CDC42P3, LY6E.
- chr8:144,772,224–145,066,685, 17 genes, copy number 5 (within-gene range 2–5): ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, AF235103.3, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr20:53,799,823–53,875,557, 2 genes, copy number 6: AC006076.1, SUMO1P1.
- chr20:57,105,741–58,911,192, 56 genes, copy number 6: AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2.
- chr20:63,488,013–64,313,132, 57 genes, copy number 5–7: EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 8,849. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
